Gene-level copy-number profile of tumor specimen C3N-04180-01 from CPTAC case C3N-04180, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 71.0 years (25,948 days).
Specimen C3N-04180-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2e7583b5-f2fc-485e-a3fb-10ec3fa00a1b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-04180-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,229 have no estimate.
https://portal.gdc.cancer.gov/files/d083096c-8272-4d0d-950a-9cd3188d568a

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 589; copy number 2: 18,870; copy number 3: 24,203; copy number 4: 10,397; copy number 5: 2,176; copy number 6: 1,305; copy number 7: 686; copy number 8: 8; copy number 9: 47; copy number 11: 110.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr19:43,192,702–43,269,530, 3 genes: PSG4, CEACAMP10, PSG9.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 844 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:57,598–71,585, 2 genes, copy number 7: OR4G11P, OR4F5.
- chr8:102,125,432–130,655,712, 348 genes, copy number 7–9 (broad region; genes not listed).
- chr8:132,866,958–142,681,968, 110 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).
- chr8:143,915,153–144,012,772, 4 genes, copy number 8–9 (within-gene range 3–9): PLEC, MIR661, PARP10, GRINA.
- chr9:60,914,407–60,964,196, 5 genes, copy number 7: SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3.
- chr14:34,515,938–57,152,177, 375 genes, copy number 7–11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 343. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
